Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABK, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABK-01A (Primary Tumor).

[page 1 of 2]
Surgery date: Surgical Pathology

ICD-O-3
Carcinoma, duct NOS
8500/3
Site: Pancreas head
625.0
9/5/14

DIAGNOSIS:

A. Common bile duct margin, excision: Negative for tumor.

B. Pancreas, duodenum, portion of jejunum, and portion of superior mesenteric vein; Whipple resection: Invasive ductal adenocarcinoma, moderately differentiated, 2.8 cm in greatest dimension, located in the uncinate process. Tumor extends beyond pancreas to involve peripancreatic soft tissue, duodenal wall, and superior mesenteric vein. Angiolymphatic and perineural invasion are present. Uncinate margin involved by carcinoma. Gallbladder with chronic cholecystitis, uninvolved by tumor. Multiple (2 of 19) lymph node involved by metastatic carcinoma.

AJCC stage (with available surgical material): pT3 N1 (7th edition).

DIAGNOSIS COMMENT:

Although tumor is present at superior mesenteric vein (superior and inferior) margins on permanent sections, tumor is not observed on the frozen section slides, which were concurrently reviewed.

Interpreted by: .

Report electronically signed by

Transcribed by:

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Common bile duct margin, excision: Negative for tumor.

B. Pancreas, duodenum, portion of jejunum, and portion of superior mesenteric vein; Whipple resection: Invasive ductal adenocarcinoma, moderately differentiated, 2.8 cm in greatest dimension, located in the uncinate process. Tumor extends beyond pancreas to involve peripancreatic soft tissue, duodenal wall, and superior mesenteric vein. Angiolymphatic and perineural invasion are present. Uncinate margin involved by carcinoma. Gallbladder with chronic cholecystitis, uninvolved by tumor. Multiple (2 of 19) lymph node involved by metastatic carcinoma. Holdover to evaluate permanent sections.

Frozen section histologic interpretation performed by:

GROSS DESCRIPTION:

A. Received fresh labeled "common bile duct margin up" is a 1.0 x 0.7 x 0.7 cm portion of bile duct with orientation. Margin submitted. Grossed by .

[page 2 of 2]
B. Received fresh labeled "total pancreas, duodenum, portion jejunum, portion superior" is a 30.5 cm segment of duodenum, a 7.9 x 4.9 x 4.8 cm apparent total pancreas, a 2.1 cm segment of superior mesenteric vein, and an 8.7 x 3.8 x 1.6 cm detached gallbladder. Upon sectioning, there is a 2.8 x 2.7 x 2.4 cm firm white infiltrative mass within the uncinate process. The mass extends to involve the duodenal wall, nearly obstructing the lumen. The mass also invades the attached superior mesenteric vein and encases an adjacent larger caliber artery, and extends to the uncinate margin. The superior and inferior margins of the superior mesenteric vein and the uncinate margins are shaved. The portal vein groove margin is submitted perpendicularly. Peripancreatic and periduodenal lymph nodes are identified. Representative sections are submitted. Research tissue collected, . Grossed by

BLOCK SUMMARY:

Part A: Common bile duct
1 Comm bile duct margin

Part B: pancreas, duodenum, portion jejunum, portion superior mesenteric vein, portion bile duct, gallbladder

- 1 Inf SMV margin
- 2 Uncinate margin 1
- 3 Uncinate margin 2
- 4 Uncinate margin 3
- 5 Uncinate margin 4
- 6 Uncinate margin 5
- 7 Sup SMV margin
- 8 Duodenal uncinate tumor
- 9 Duodenal uncinate tumor
- 10 Tumor sup mesenteric artery
- 11 Tumor sup mesenteric artery
- 12 Tumor SMV
- 13 Portal vein groove mgn
- 14 Portal vein groove mgn
- 15 Tumor/peripanc ST
- 16 Gallbladder wall
- 17 Gallbladder LN 1(B1)
- 18 Periduodenal LN 4(B1)
- 19 Periduodenal LN 5(B2)
- 20 Periduodenal LN 3(B3)
- 21 Periduodenal LN 2(B4)
- 22 Periduodenal LN 2(B5)
- 23 Peripancreatic LN 4(B6)
- 24 Peripancreatic LN 2(B7)
- 25 Peripancreatic LN 5(B8)
- 26 Peripancreatic LN 3(B9)
- 27 Peripancreatic LN 1(B10)

Source: NCI Genomic Data Commons file 80b62011-c090-4fdf-b651-8c97eb02db99 (TCGA-2J-AABK.2B943B62-8FF9-4719-AD78-78546FB843B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).